Surgical pathology report (de-identified scan), TCGA case TCGA-69-7979, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-7979-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] / F

SPECIMEN SUBMITTED:

Part A: L4

Part B: 7

Part C: 4R

Part D: 3

Part E: 2R

Part F: 2L

Part G: CHEST WALL MASS

Part H: BRONCHIAL MARGIN

Part I: LEVEL 10

Part J: LEVEL 11

Part K: R11 POSTERIOR

Final Diagnosis

1. L4, lymph node, excision (A) - One lymph node negative for malignancy.
2. 7, lymph node, excision (B) - One lymph node negative for malignancy.
3. 4R, lymph node, excision (C) - One lymph node negative for malignancy.
4. 3, lymph node, excision (D) - One lymph node negative for malignancy.
5. 2R, lymph node, excision (E) - One lymph node negative for malignancy.
6. 2L, lymph node, excision (F) - One lymph node negative for malignancy.
7. Chest wall, partial excision (G) - One lymph node negative for malignancy.
- Unremarkable fibroadipose tissue.
8. Right upper lobe, lobectomy (H) - Invasive adenocarcinoma, acinar type.
- Surgical margins negative for neoplasm.
- Two lymph nodes negative for carcinoma.
- Emphysematous changes.
9. Level 10, lymph node, biopsy (I) - One lymph node negative for neoplasm.
10. Level 11, lymph node, excision (J) - One lymph node negative for neoplasm.
11. R11 posterior, lymph node, excision (K) - One lymph node negative for neoplasm.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

Tumor Location: Right upper lobe

Tumor Size: 3.2 x 3.1 x 2.1 cm

Vascular Invasion: Not identified

Lymphatic Invasion: Not identified

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: Negative

Pathologic Stage (AJCC): pT2a pN0 pMX Stage 1b

Intraoperative Diagnosis:

- A. Negative for neoplasm
- B. Negative for neoplasm
- C. Negative for neoplasm
- D. Negative for neoplasm
- E. Negative for neoplasm .
- F. Negative for neoplasm
- G. Negative for neoplasm .
- H. Negative for tumor

Clinical Diagnosis:

LUNG CA

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh at the frozen desk labeled "L4" is a 0.2 x 0.1 x 0.1 cm tan-red soft tissue fragment. The specimen is totally submitted for frozen section in one cassette labeled A1.

B. Received fresh at the frozen desk labeled "7" are multiple fragments of tan-brown soft tissue measuring 1.7 x 0.7 x 0.2 cm in aggregate. The specimen is totally submitted for frozen section in one cassette labeled B1.

C. Received fresh at the frozen desk labeled "4R" are multiple fragments of tan-brown soft tissue measuring in aggregate 1 x 0.5 x 0.2 cm. The specimen is totally submitted for frozen section in one cassette labeled C1.

D. Received fresh at the frozen desk labeled "3" are multiple fragments of tan-brown soft tissue measuring 2.2 x 2 x 0.4 cm in aggregate. The specimen is totally submitted in two cassettes labeled D1-D2.

E. Received fresh at the frozen desk labeled "2R" is a single tan-pink soft tissue fragment measuring 0.7 x 0.5 x 0.3 cm. The specimen is totally submitted for frozen section in one cassette labeled E1.

F. Received fresh at the frozen desk labeled "2L" are two fragments of yellow-tan soft tissue measuring 0.6 x 0.2 x 0.2 cm. The specimen is totally submitted for frozen section in one cassette labeled F1.

G. Received fresh at the frozen desk labeled "chest wall mass" is a single segment of yellow-tan soft tissue measuring 1.5 x 0.6 x 0.3 cm. The specimen is bisected and totally submitted for frozen section in one cassette labeled G1.

H. Received fixed in formalin is a specimen labeled "bronchial margin." The specimen consists of a right upper lobectomy specimen (15 x 11 x 3 cm; 199 grams) and bronchial remnant (1.1 cm in length and 0.9 cm in diameter). At the apex, there is a poorly circumscribed stellate firm gray-white tumor (3.2 x 3.1 x 2.1 cm) with central necrosis that is 4 cm from the bronchial margin and 2.5 cm from the parenchymal margin. The tumor causes retraction of the overlying pleura but does not grossly invade the pleura, which has a smooth glistening surface. Also in the apical portion of the specimen is a separate nodule (1 x 0.6 x 0.5 cm) that is 5 cm from the primary mass and adjacent to the pleura. This second small nodule is tan with central hemorrhage. The remainder of the lung demonstrates severe emphysematous changes, mostly in the upper portion. Two anthracotic peribronchial lymph nodes are seen, the larger measuring 0.8 cm in greatest dimension. Representative sections are submitted as follows: FSH1 bronchial margin; H2 vascular margins; H3 tumor with overlying pleura (blue); H4-H5 tumor; H6 parenchymal margin (orange); H7-H8 separate nodule; H9 non-tumoral lung; H10 lymph nodes.

I. Received fresh on Telfa gauze labeled "level 10" is a single anthracotic nodule with minimal attached tissue measuring 1.4 x 0.8 x 0.5 cm. The specimen is totally submitted in one cassette.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

J. Received fresh on Telfa gauze labeled "level 11" is one anthracotic nodule measuring 1.5 x 1.2 x 0.8 cm. The specimen is totally submitted in one cassette.

K. Received fresh on Telfa gauze labeled "right 11 posterior" is one anthracotic nodule measuring 1.0 x 0.5 x 0.3 cm. The specimen is totally submitted in one cassette.

Source: NCI Genomic Data Commons file 33435e37-f95a-4a49-9cf4-0fb40c4facd7 (TCGA-69-7979.98F68D62-141D-4F50-9987-6E13D35195D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).